Somatic mutation profile of tumor specimen C3N-01349-02 (aliquot CPT0116630006) from CPTAC case C3N-01349, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 77.3 years (28,217 days).
Specimen C3N-01349-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a290b19-7fdb-4af9-a536-68c099bf989f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01349-31 (Blood Derived Normal), aliquot CPT0116700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/064e93c5-c828-49ea-8237-0ae6589527d4

The open-access MAF lists 144 somatic variants for this specimen: 108 protein-altering or splice-affecting, 25 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 25, Intron 8, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, 3'UTR 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 80/166 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/205 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 27/445 reads (6%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- RBM20 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs796734066, CM107456; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 160/547 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>C p.X225_splice | Splice Site (SNP) | VAF 137/370 reads (37%) | hotspot (GDC flag); catalogued as CS109519, COSV52669186, COSV52682653, COSV52687702; called by muse, mutect2, varscan2
- ACTN1 | c.1870C>G p.R624G | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV51996326; called by muse, mutect2, varscan2
- ADGRG5 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs149449822; called by muse, mutect2, varscan2
- AGRN | c.3161C>T p.A1054V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs377535426; called by muse, mutect2, varscan2
- AKT1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 114/270 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as COSV62573390; called by muse, mutect2, varscan2
- ARMCX2 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs782811435, COSV57529832; called by mutect2, varscan2
- BCORL1 | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1334382828, COSV54396407; called by muse, mutect2
- BICC1 | c.2411G>A p.R804H | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs372894085; ClinVar: uncertain significance; called by mutect2, varscan2
- C2CD2L | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755659659; called by muse, mutect2, varscan2
- CBX8 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1187980031; called by muse, mutect2, varscan2
- CD46 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245287864, CD109987, CM1110318; called by muse, mutect2, varscan2
- CNGB3 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 31/400 reads (8%) | catalogued as COSV60684744, COSV60694651; called by muse, mutect2
- COL6A3 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs771091001; ClinVar: uncertain significance; called by muse, mutect2
- CTNNA2 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63560724; called by muse, mutect2, varscan2
- CYP11B1 | c.207C>G p.H69Q | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.328); catalogued as rs776502555; called by muse, mutect2
- DDX43 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 7/140 reads (5%) | catalogued as COSV64813800; called by muse, mutect2
- DUSP29 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs149175172, COSV100633361; called by muse, mutect2
- EXOC3 | c.1880C>A p.A627D | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100155275; called by muse, mutect2
- FAM81A | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs1229510489; called by muse, mutect2, varscan2
- FAT4 | c.10663C>T p.P3555S | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as rs1172861411; called by muse, mutect2, varscan2
- FRMD4A | c.1544A>G p.N515S | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs767331828; called by muse, mutect2, varscan2
- GRM6 | c.2345C>A p.A782D | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51447282; called by muse, mutect2
- HCLS1 | c.624C>T p.S208= | Splice Region (SNP) | VAF 24/176 reads (14%) | catalogued as rs767328288; called by muse, mutect2, varscan2
- HOXB3 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs773338030; called by muse, mutect2, varscan2
- IKBKB | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV60596575; called by muse, mutect2, varscan2
- JPH1 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 74/404 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs900020423, COSV60609027; called by muse, mutect2, varscan2
- KCTD8 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs979707878; called by muse, mutect2
- KNDC1 | c.5051C>T p.A1684V | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs749712577, COSV58840290; called by muse, mutect2, varscan2
- LRRK2 | c.7325G>A p.R2442H | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs749224394, COSV100108924; called by muse, mutect2
- MERTK | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs755422343, COSV54933937; called by muse, mutect2
- MYO7A | c.2440C>T p.R814C | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265801629; called by muse, mutect2, varscan2
- NDST1 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs770302254; called by muse, mutect2, varscan2
- NMT1 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs867687573; called by muse, mutect2, varscan2
- OR10C1 | c.784C>T p.R262C (on ENST00000622521; = p.R260C on NM_013941.3) | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs1358295170, COSV65822163, COSV65823505; called by muse, mutect2, varscan2
- PLA2G15 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs763293807, COSV54720860; called by muse, mutect2, varscan2
- POU3F4 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs773886219, CM098352; called by muse, mutect2, varscan2
- PRSS12 | c.1631+2T>G p.X544_splice | Splice Site (SNP) | VAF 15/292 reads (5%) | catalogued as COSV56607131; called by muse, mutect2
- RELN | c.6538G>T p.D2180Y | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58991449; called by muse, mutect2
- SGK3 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV61894231; called by muse, mutect2
- SI | c.4825C>T p.R1609* | Nonsense Mutation (SNP) | VAF 23/315 reads (7%) | catalogued as rs200328403; called by muse, mutect2
- SLITRK5 | c.2285A>T p.N762I | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100280328, COSV100281069, COSV61522559; called by muse, mutect2
- SPRING1 | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99732224; called by muse, mutect2
- SPTA1 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as rs887993336, COSV63750683; called by muse, mutect2
- STXBP5L | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56503790; called by muse, mutect2, varscan2
- TNFRSF13B | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 44/602 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs779924436; called by muse, mutect2
- VWF | c.6931C>T p.R2311C | Missense Mutation (SNP) | VAF 81/409 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs150725355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR49 | c.1238C>T p.A413V (on ENST00000308378 / NM_001366158.1; = p.A754V on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV57712625; called by muse, mutect2, varscan2
- ABCA6 | c.4372G>A p.V1458I | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- ADGB | c.2008G>A p.V670M | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); called by muse, mutect2
- ANKS1B | c.2150G>A p.G717E | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO4 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ANPEP | c.1186G>C p.G396R | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPERG | c.1493A>C p.Q498P | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CHD3 | c.3248C>T p.S1083L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CHST15 | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CWC22 | c.1157A>G p.K386R | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDX43 | c.1412A>T p.E471V | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2
- DNAH3 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- DOCK5 | c.3707G>A p.R1236K | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- DUSP7 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2
- EPG5 | c.5419A>T p.I1807F | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); called by muse, mutect2
- FAM161A | c.641G>T p.C214F | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXA2 | c.656del p.K219Rfs*45 (on ENST00000377115 / NM_153675.3; = p.K225Rfs*45 on NM_021784.5) | Frame Shift Del (DEL) | VAF 80/263 reads (30%) | called by mutect2, pindel, varscan2
- FSTL5 | c.1772T>A p.V591E | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- HECTD1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- HNRNPA3 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- HS3ST1 | c.524A>G p.E175G | Missense Mutation (SNP) | VAF 70/312 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- JAG1 | c.2093A>T p.K698I | Missense Mutation (SNP) | VAF 23/576 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KAT6A | c.3238T>A p.F1080I | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.053); called by muse, mutect2
- KCMF1 | c.925A>G p.M309V | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA2012 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.091); called by muse, mutect2
- LAS1L | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPIN1 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAEL | c.1050G>C p.R350S | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- MAEL | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGEC3 | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MATR3 | c.1710del p.K571Nfs*7 | Frame Shift Del (DEL) | VAF 42/408 reads (10%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.8885A>G p.K2962R (on ENST00000357337; = p.K3000R on NM_015057.5) | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MYLIP | c.214T>G p.Y72D | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); called by muse, mutect2
- NARS1 | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NAV3 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NEXMIF | c.322G>C p.G108R | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- OR5K4 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2
- PCBP2 | c.392T>A p.V131D | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PKMYT1 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.365); called by muse, mutect2
- PLEC | c.8080C>G p.R2694G (on ENST00000322810 / NM_201380.4; = p.R2584G on NM_000445.5) | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2
- PSMB8 | c.407+2T>A p.X136_splice (on ENST00000374882 / NM_148919.4; = p.X132_splice on NM_004159.5) | Splice Site (SNP) | VAF 46/522 reads (9%) | called by muse, mutect2
- RAMP2 | c.44C>G p.P15R | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.278); called by muse, mutect2
- SLC4A11 | c.1676G>T p.S559I | Missense Mutation (SNP) | VAF 66/499 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- SPG7 | c.1156C>T p.L386F (on ENST00000268704; = p.L393F on NM_003119.4) | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TBC1D23 | c.2030C>T p.P677L (on ENST00000394144 / NM_001199198.3; = p.P662L on NM_018309.5) | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMEM132C | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TRAPPC9 | c.751T>G p.S251A | Missense Mutation (SNP) | VAF 43/391 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TRIM41 | c.1084C>A p.R362S | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.095); called by muse, mutect2
- TRIM75P | c.26del p.G9Dfs*15 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- TYRP1 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZFC3H1 | c.2981A>T p.Q994L | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.049); called by muse, mutect2
- ZNF121 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF280A | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- ZNF280D | c.2529A>T p.Q843H | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- ZNF326 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF420 | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ZNF611 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- APOE | c.849C>T p.F283= | Silent (SNP) | VAF 44/566 reads (8%) | catalogued as rs954301448; called by muse, mutect2
- ARFGAP3 | c.363C>T p.A121= | Silent (SNP) | VAF 84/170 reads (49%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.1494G>A p.K498= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as COSV53645342; called by muse, mutect2
- ASCC3 | c.6135G>C p.S2045= | Silent (SNP) | VAF 30/381 reads (8%) | catalogued as rs147694095; called by muse, mutect2
- COL3A1 | c.1701G>A p.G567= | Silent (SNP) | VAF 25/250 reads (10%) | catalogued as rs765802289; ClinVar: likely benign; called by muse, mutect2
- COL6A3 | c.7122C>T p.I2374= | Silent (SNP) | VAF 38/490 reads (8%) | catalogued as rs747377101; called by muse, mutect2
- CTPS1 | c.1077G>A p.Q359= | Silent (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- DCDC1 | c.3906C>T p.N1302= (on ENST00000597505 / NM_001367979.1; = p.N409= on NM_020869.3) | Silent (SNP) | VAF 35/57 reads (61%) | called by muse, mutect2, varscan2
- ENPP1 | c.2061C>T p.I687= | Silent (SNP) | VAF 80/216 reads (37%) | called by muse, mutect2, varscan2
- FADS1 | c.963A>G p.K321= | Silent (SNP) | VAF 147/230 reads (64%) | catalogued as rs779394900; called by muse, mutect2, varscan2
- FFAR1 | c.858G>A p.K286= | Silent (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2
- GMDS | c.1118G>A p.*373= | Silent (SNP) | VAF 43/296 reads (15%) | catalogued as COSV101070496; called by muse, mutect2, varscan2
- HS3ST3A1 | c.519C>G p.R173= | Silent (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- KLHL5 | c.606T>C p.H202= | Silent (SNP) | VAF 19/183 reads (10%) | called by muse, mutect2, varscan2
- MEFV | c.759G>T p.A253= | Silent (SNP) | VAF 40/363 reads (11%) | catalogued as rs936508032; called by muse, mutect2, varscan2
- PPP1R13L | c.981C>A p.G327= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- SPRR4 | c.87A>G p.P29= | Silent (SNP) | VAF 20/398 reads (5%) | called by muse, mutect2
- TMEM62 | c.1395T>C p.F465= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- TNXB | c.10284G>A p.S3428= (on ENST00000647633; = p.S3181= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/476 reads (5%) | catalogued as rs745855356; called by muse, mutect2
- WDFY4 | c.5679G>A p.K1893= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- XDH | c.3870C>T p.N1290= | Silent (SNP) | VAF 31/249 reads (12%) | catalogued as rs774319963, COSV101052003; called by muse, mutect2, varscan2
- XRRA1 | c.2229G>A p.L743= | Silent (SNP) | VAF 14/426 reads (3%) | called by muse, mutect2
- ZIC1 | c.57G>A p.A19= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as rs756393471, COSV51550355, COSV51557226; called by muse, mutect2, varscan2
- ZNF124 | c.309C>G p.S103= | Silent (SNP) | VAF 52/206 reads (25%) | called by muse, mutect2, varscan2
- ZRANB1 | c.882G>A p.Q294= | Silent (SNP) | VAF 75/200 reads (38%) | catalogued as rs756486937; called by muse, mutect2, varscan2
- ALKBH6 | c.336+16C>T | Intron (SNP) | VAF 26/167 reads (16%) | catalogued as rs369899533; called by muse, mutect2, varscan2
- ARFGEF1 | c.5385+75C>T | Intron (SNP) | VAF 30/349 reads (9%) | catalogued as rs777535315; called by muse, mutect2
- IL12RB1 | c.*43G>A | 3'UTR (SNP) | VAF 28/180 reads (16%) | catalogued as rs754507050; called by muse, mutect2, varscan2
- IL7R | c.379+55T>A | Intron (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- ISM2 | c.141+212G>C | Intron (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- KIF3A | c.1229-2838C>G | Intron (SNP) | VAF 9/195 reads (5%) | called by muse, mutect2
- PPIH | c.243+49T>G | Intron (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- SLC9A3R2 | c.856-69G>A | Intron (SNP) | VAF 10/78 reads (13%) | catalogued as rs1198651926; called by muse, mutect2, varscan2
- SNORD114-23 | chr14:100986031 C>T | 3'Flank (SNP) | VAF 17/46 reads (37%) | catalogued as rs763301104; called by muse, mutect2, varscan2
- ZDHHC3 | c.*8702C>T | 3'UTR (SNP) | VAF 41/326 reads (13%) | catalogued as rs1418336427; called by muse, mutect2, varscan2
- ZNF783 | c.802+3462G>C | Intron (SNP) | VAF 10/70 reads (14%) | catalogued as rs755765981; called by muse, mutect2, varscan2
